Gene-level copy-number profile of tumor specimen TCGA-AF-6672-01A from TCGA case TCGA-AF-6672, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 43.7 years (15,965 days).
Specimen TCGA-AF-6672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.dda6add0-a56e-4693-9732-159ebf4e0ee5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-6672-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f63a086-cbc4-4cc6-bc30-6e46edf718aa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,415; copy number 2: 14,903; copy number 3: 27,199; copy number 4: 9,730; copy number 5: 5,628; copy number 6: 551; copy number 9: 376; copy number 10: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AF-6672-01A-11D-1825-01): tumor purity 0.71, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–331,026, 12 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 381 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:135,662,496–135,693,418, 1 gene, copy number 10 (within-gene range 2–10): STMP1.
- chr7:135,681,237–135,932,997, 4 genes, copy number 10 (within-gene range 6–10): SLC13A4, AC091736.1, FAM180A, AC015987.1.
- chr18:47,390–15,330,282, 376 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,415. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
